Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AALQ, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AALQ-01A (Primary Tumor).

Concerning

Summary pathology report

Right orchiectomy; nonseminoma (YST 80%, MT+IT 19%, EC 1%, scattered trophoblastic giant cells); diameter 4 cm; no angio-invasion; no invasion of rete testis; tumor confined to testis.

Date of procurement (= date of orchiectomy):

ICD-O-3
Sperm cell tumor mixed 9885/3
Site: B Testis NOS C62.9
gn 01/01/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 49dbc4b5-5576-4264-a83e-4f5c3b3f0448 (TCGA-2G-AALQ.0ED757C0-F9E2-45E0-898B-67C14CF632AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).